Somatic mutation profile of tumor specimen C3N-03008-01 (aliquot CPT0245010009) from CPTAC case C3N-03008, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,789 days).
Specimen C3N-03008-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87158fd5-d814-45e0-a961-5c4dcc52ad03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03008-31 (Blood Derived Normal), aliquot CPT0245050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f65eb7fe-0e64-4325-ae08-ee0e4d3bd374

The open-access MAF lists 194 somatic variants for this specimen: 129 protein-altering or splice-affecting, 45 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 45, Nonsense Mutation 12, Intron 9, 3'UTR 5, Splice Region 3, 5'UTR 3, Frame Shift Ins 3, In Frame Del 3, Frame Shift Del 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 172/403 reads (43%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2, varscan2
- SLC46A1 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs80338773, CM073361; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 83/342 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52717368, COSV53120630; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 115/478 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1378418466; called by muse, mutect2, varscan2
- AHNAK | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs750313527, COSV57224219; called by muse, mutect2, varscan2
- ARHGEF3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750336883, COSV56325297; called by muse, mutect2, varscan2
- BPI | c.593G>C p.R198P (on ENST00000262865; = p.R194P on NM_001725.3) | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- BUB1B | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 102/467 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs774654439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768783826; called by muse, mutect2, varscan2
- C17orf64 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as rs201203253; called by muse, mutect2, varscan2
- CFHR4 | c.1515G>A p.W505* (on ENST00000367416 / NM_001201551.2; = p.W259* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 54/240 reads (23%) | catalogued as COSV52231867; called by muse, mutect2, varscan2
- CSMD3 | c.3089C>A p.S1030Y (on ENST00000297405 / NM_001363185.1; = p.S926Y on NM_052900.3) | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV99840782; called by muse, mutect2, varscan2
- DMP1 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99218576; called by muse, mutect2, varscan2
- FAT1 | c.7789C>T p.R2597* | Nonsense Mutation (SNP) | VAF 66/172 reads (38%) | catalogued as rs777631605, COSV71672084; called by muse, mutect2, varscan2
- FPGT | c.1765A>G p.M589V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs747063121; called by muse, mutect2, varscan2
- HDAC7 | c.1804G>A p.G602R (on ENST00000427332; = p.G641R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs762203099, COSV99315977; called by muse, mutect2, varscan2
- HLA-B | c.74-2A>G p.X25_splice | Splice Site (SNP) | VAF 112/308 reads (36%) | catalogued as rs151341086; called by muse, mutect2, varscan2
- HSPA12B | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370512373; called by muse, mutect2, varscan2
- ITGA10 | c.3429C>G p.C1143W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100994817; called by muse, mutect2, varscan2
- KCNA3 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV63902378; called by muse, mutect2, varscan2
- LY6L | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as rs545945558; called by muse, mutect2
- MRTFB | c.2567C>T p.P856L (on ENST00000571589 / NM_001365412.2; = p.P806L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs760452098; called by muse, mutect2, varscan2
- MYO9B | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs997783083; called by muse, mutect2, varscan2
- NPIPB7 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 73/1074 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.024); catalogued as rs750543375, COSV71745109; called by muse, mutect2
- OR52B6 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61448349; called by muse, mutect2, varscan2
- PIEZO2 | c.1404G>C p.E468D | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV57463790; called by muse, mutect2, varscan2
- POTEH | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 30/730 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as rs1391383282; called by muse, mutect2
- PPARGC1B | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58526836; called by muse, mutect2, varscan2
- PRAMEF4 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 204/784 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.088); catalogued as COSV99339982; called by muse, mutect2, varscan2
- PRF1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as rs150558419, CM044249, CM119723; called by muse, mutect2, varscan2
- RIMBP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs776954273; called by muse, mutect2, varscan2
- RIMS2 | c.1522C>T p.R508C (on ENST00000666250 / NM_001348490.2; = p.R316C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376615886; called by muse, mutect2, varscan2
- RLBP1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 126/500 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs761816415, COSV99175352; called by muse, mutect2, varscan2
- SBF1 | c.4522G>A p.V1508I | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs371044439; called by muse, mutect2, varscan2
- SPTB | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs573498417, COSV67634904; called by muse, mutect2, varscan2
- TJP1 | c.1886A>T p.K629M | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633219; called by muse, mutect2, varscan2
- TMC1 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs868082421, COSV52783753; called by muse, mutect2, varscan2
- TMOD4 | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs749657856; called by muse, mutect2, varscan2
- TNN | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 162/553 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs200671106, COSV53420917; called by muse, mutect2, varscan2
- TTN | c.32780C>G p.P10927R (on ENST00000591111; = p.P10000R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/263 reads (28%) | PolyPhen possibly damaging (0.789); catalogued as COSV59864966, COSV60085696; called by muse, mutect2, varscan2
- TTN | c.28993G>A p.A9665T (on ENST00000591111; = p.A8738T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs200745162, COSV60095488; ClinVar: uncertain significance; called by muse, mutect2
- VPS13A | c.3818G>A p.R1273Q | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201135133, COSV100652867; called by muse, mutect2, varscan2
- XIRP2 | c.9959G>C p.G3320A (on ENST00000628543; = p.G3495A on NM_152381.6) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54693377; called by muse, mutect2, varscan2
- ZNF618 | c.2066C>T p.S689F (on ENST00000374126 / NM_001318042.2; = p.S596F on NM_133374.2) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV55921835; called by muse, mutect2, varscan2
- ZYG11A | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1454775208; called by muse, mutect2, varscan2
- ABCC5 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 109/432 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABCC9 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1621T>A p.Y541N | Missense Mutation (SNP) | VAF 196/538 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADAM18 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADORA2B | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AGBL4 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AIMP2 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 102/288 reads (35%) | called by muse, mutect2, varscan2
- ATP23 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ATP9A | c.2547_2561del p.R849_I853del | In Frame Del (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- ATXN1 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ATXN3 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- BAHCC1 | c.6929A>G p.E2310G | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- BHLHE41 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.04); called by muse, varscan2
- BMPR1A | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BTBD18 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- C6orf15 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CCDC88A | c.1773T>G p.I591M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CEP95 | c.1820C>A p.S607* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- CFAP47 | c.4348G>T p.D1450Y | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- COMMD2 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYFIP1 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DMPK | c.1286T>A p.L429H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- DNMBP | c.3545G>A p.C1182Y | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSC1 | c.1246C>A p.L416M | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DUS1L | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ELF1 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- EVX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBLL1 | c.574del p.I192Sfs*53 | Frame Shift Del (DEL) | VAF 26/212 reads (12%) | called by mutect2, pindel, varscan2
- FMN2 | c.2047A>T p.I683F | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FURIN | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GAB4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLT1D1 | c.832G>T p.A278S (on ENST00000442111 / NM_001366889.1; = p.A198S on NM_144669.3) | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GRIK5 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HECTD3 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- HIVEP1 | c.978T>G p.Y326* | Nonsense Mutation (SNP) | VAF 110/201 reads (55%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2112C>A p.S704R | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- KCNJ2 | c.206dup p.A70Rfs*69 | Frame Shift Ins (INS) | VAF 61/260 reads (23%) | called by mutect2, pindel, varscan2
- KDM6B | c.4282_4285dup p.G1429Afs*16 | Frame Shift Ins (INS) | VAF 94/502 reads (19%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 79/489 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KLHL2 | c.1194A>C p.L398F | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMLN2 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LRP1B | c.1910A>C p.K637T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEL2 | c.2708T>C p.L903P | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MBL2 | c.192A>T p.Q64H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- MED16 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MEGF6 | c.729C>T p.V243= | Splice Region (SNP) | VAF 61/214 reads (29%) | called by muse, mutect2, varscan2
- MOGAT2 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH11 | c.3196_3202delinsA p.D1066_H1068delinsN | In Frame Del (DEL) | VAF 76/463 reads (16%) | called by pindel, varscan2*
- NKTR | c.3258T>A p.D1086E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP7 | c.1750G>C p.A584P | Missense Mutation (SNP) | VAF 142/566 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- OPA1 | c.951A>G p.K317= (on ENST00000361510 / NM_130837.3; = p.K262= on NM_015560.3) | Splice Region (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- OR5T1 | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OSBP2 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- PFN2 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PFN4 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIKFYVE | c.4007C>G p.S1336* | Nonsense Mutation (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.2703C>A p.C901* | Nonsense Mutation (SNP) | VAF 47/252 reads (19%) | called by muse, mutect2, varscan2
- PRDM2 | c.2504A>T p.E835V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PRND | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 140/465 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PTPRM | c.237del p.Q80Rfs*39 | Frame Shift Del (DEL) | VAF 27/147 reads (18%) | called by mutect2, pindel, varscan2
- RAB9A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RANBP6 | c.142T>A p.C48S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRF1 | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM22 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- SIPA1L2 | c.4063C>G p.H1355D | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SOBP | c.2283G>T p.E761D | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, varscan2
- SORBS2 | c.88T>C p.S30P (on ENST00000284776 / NM_021069.5; = p.S76P on NM_003603.6) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- SPATC1 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 139/671 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SREBF2 | c.1178_1189del p.V393_L396del | In Frame Del (DEL) | VAF 60/620 reads (10%) | called by mutect2, pindel
- STK10 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SULF1 | c.2513A>G p.Y838C | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TNKS1BP1 | c.1723dup p.T575Nfs*2 | Frame Shift Ins (INS) | VAF 29/121 reads (24%) | called by mutect2, pindel, varscan2
- TRIM4 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM42 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 145/635 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- TRIM49B | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXNDC11 | c.910A>T p.N304Y (on ENST00000356957 / NM_001303447.2; = p.N277Y on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- UBE2R2 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UBE2V2 | c.166-7C>A | Splice Region (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- USP13 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCAN | c.2819T>C p.V940A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS51 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- XIRP2 | c.8929G>T p.E2977* (on ENST00000628543; = p.E3152* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 40/188 reads (21%) | called by mutect2, varscan2
- XKR4 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ABCB10 | c.450A>T p.A150= | Silent (SNP) | VAF 78/349 reads (22%) | called by muse, mutect2, varscan2
- AC024598.1 | c.963A>G p.Q321= | Silent (SNP) | VAF 27/237 reads (11%) | called by muse, mutect2, varscan2
- AC093155.3 | c.906A>C p.A302= | Silent (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1485G>A p.L495= (on ENST00000296862 / NM_001368115.2; = p.L427= on NM_153839.7) | Silent (SNP) | VAF 77/314 reads (25%) | catalogued as rs1351705554; called by muse, mutect2, varscan2
- ARMC4 | c.2148T>C p.L716= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- ATP2C1 | c.1905C>T p.N635= | Silent (SNP) | VAF 101/509 reads (20%) | catalogued as rs781604274; called by muse, mutect2, varscan2
- CHD1L | c.2361T>C p.D787= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as rs1553970515; called by muse, varscan2
- EFCC1 | c.1335C>T p.G445= | Silent (SNP) | VAF 66/370 reads (18%) | catalogued as rs148256726; called by muse, mutect2, varscan2
- ENTPD7 | c.1578A>C p.P526= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ESYT2 | c.2241C>T p.I747= (on ENST00000613624; = p.I671= on NM_020728.3) | Silent (SNP) | VAF 33/292 reads (11%) | catalogued as rs1266244011; called by muse, mutect2, varscan2
- GPHB5 | c.261C>T p.N87= | Silent (SNP) | VAF 48/269 reads (18%) | catalogued as rs376425106; called by muse, mutect2, varscan2
- GRIP2 | c.3051G>A p.E1017= (on ENST00000619221; = p.E920= on NM_001080423.4) | Silent (SNP) | VAF 53/169 reads (31%) | called by muse, mutect2, varscan2
- IQCA1 | c.2304T>A p.T768= | Silent (SNP) | VAF 70/289 reads (24%) | catalogued as rs981234813; called by muse, mutect2, varscan2
- ITGA8 | c.1080C>A p.I360= | Silent (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- KRT37 | c.630G>A p.T210= | Silent (SNP) | VAF 70/271 reads (26%) | catalogued as rs779203297, COSV56656764; called by muse, mutect2, varscan2
- LARP4B | c.798C>T p.N266= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- LCT | c.4626T>A p.I1542= | Silent (SNP) | VAF 128/521 reads (25%) | called by muse, mutect2, varscan2
- MAGI1 | c.1536G>A p.K512= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs767673510; called by muse, mutect2, varscan2
- MGAM2 | c.4170C>T p.C1390= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- MLXIP | c.1809C>T p.T603= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs775366952; called by muse, mutect2, varscan2
- MROH6 | c.1338G>A p.L446= | Silent (SNP) | VAF 185/425 reads (44%) | called by muse, mutect2, varscan2
- MUC5AC | c.1866G>A p.E622= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- NPAP1 | c.3342T>C p.P1114= | Silent (SNP) | VAF 84/358 reads (23%) | catalogued as rs763855911; called by muse, mutect2, varscan2
- PHKB | c.801G>T p.V267= | Silent (SNP) | VAF 84/393 reads (21%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.2838G>A p.P946= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as rs188910942; called by muse, mutect2, varscan2
- PPP1R13L | c.468G>A p.A156= | Silent (SNP) | VAF 47/159 reads (30%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1458C>A p.V486= | Silent (SNP) | VAF 91/408 reads (22%) | catalogued as COSV59049279; called by muse, mutect2, varscan2
- PRDM1 | c.2118G>C p.L706= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV64845028; called by muse, mutect2, varscan2
- PRDM1 | c.2316G>A p.L772= | Silent (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- RASAL2 | c.114C>T p.V38= | Silent (SNP) | VAF 75/666 reads (11%) | called by muse, mutect2, varscan2
- RBM25 | c.1713G>A p.R571= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV56200029; called by muse, varscan2
- RIMS1 | c.4806T>G p.P1602= | Silent (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- SENP1 | c.819T>G p.S273= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- SERPINC1 | c.1077C>T p.D359= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs773134244, COSV62928797; called by muse, mutect2, varscan2
- SLC12A8 | c.1242G>T p.P414= | Silent (SNP) | VAF 56/307 reads (18%) | called by muse, mutect2, varscan2
- SLC35D3 | c.1191G>A p.R397= | Silent (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- SLC35G1 | c.57A>T p.L19= | Silent (SNP) | VAF 112/347 reads (32%) | called by muse, mutect2, varscan2
- TBX10 | c.132T>A p.T44= | Silent (SNP) | VAF 30/632 reads (5%) | called by muse, mutect2
- TDRD6 | c.5622G>A p.P1874= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs549944300; called by muse, mutect2, varscan2
- TRAM1L1 | c.930C>T p.Y310= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs548978348, COSV60291701; called by muse, mutect2, varscan2
- WDR97 | c.4395G>A p.P1465= | Silent (SNP) | VAF 60/278 reads (22%) | catalogued as rs1423464966; called by muse, mutect2, varscan2
- ZBTB7C | c.1770G>A p.P590= | Silent (SNP) | VAF 215/584 reads (37%) | catalogued as rs766210423; called by muse, mutect2, varscan2
- ZGPAT | c.1371G>A p.L457= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56650937; called by muse, mutect2, varscan2
- ZNF207 | c.1011T>C p.N337= | Silent (SNP) | VAF 92/395 reads (23%) | called by muse, mutect2, varscan2
- ZNF813 | c.531C>A p.S177= | Silent (SNP) | VAF 67/308 reads (22%) | catalogued as COSV67177864; called by muse, mutect2, varscan2
- AC243919.1 | n.128G>A | RNA (SNP) | VAF 50/307 reads (16%) | catalogued as rs1167297370; called by muse, mutect2, varscan2
- AKT2 | c.-5C>T | 5'UTR (SNP) | VAF 108/523 reads (21%) | catalogued as rs777810125; called by muse, mutect2, varscan2
- AKT2 | c.-6G>T | 5'UTR (SNP) | VAF 109/520 reads (21%) | called by muse, mutect2, varscan2
- ATP8A2 | c.507+875C>A | Intron (SNP) | VAF 54/123 reads (44%) | catalogued as COSV54948195; called by muse, mutect2, varscan2
- COBL | c.1096+2064C>T | Intron (SNP) | VAF 38/126 reads (30%) | catalogued as rs766921546; called by muse, varscan2
- DIP2A | c.1922-39C>T | Intron (SNP) | VAF 66/226 reads (29%) | called by muse, mutect2, varscan2
- DST | c.21517-15C>A | Intron (SNP) | VAF 42/140 reads (30%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-2545C>A | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- IL20RB | c.407-2677A>T | Intron (SNP) | VAF 68/166 reads (41%) | called by muse, mutect2, varscan2
- ITGA4 | c.*2354C>G | 3'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- KCNH2 | c.1945+9G>T | Intron (SNP) | VAF 41/303 reads (14%) | called by muse, mutect2, varscan2
- MYPN | c.*958G>T | 3'UTR (SNP) | VAF 16/200 reads (8%) | catalogued as rs537455141; called by muse, mutect2
- NFASC | c.706+4301G>A | Intron (SNP) | VAF 26/121 reads (21%) | catalogued as rs775761181, COSV100362979; called by muse, mutect2, varscan2
- P2RY11 | c.*418A>G | 3'UTR (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- PINK1 | c.*29_*46del | 3'UTR (DEL) | VAF 50/229 reads (22%) | called by mutect2, pindel
- PLEKHM1 | c.-42+2873G>A | Intron (SNP) | VAF 25/153 reads (16%) | catalogued as rs1416103158; called by muse, mutect2, varscan2
- PPP5D1 | n.399T>A | RNA (SNP) | VAF 82/260 reads (32%) | called by muse, mutect2, varscan2
- RUFY3 | chr4:70793790 G>A | 3'Flank (SNP) | VAF 75/313 reads (24%) | catalogued as rs372273317; called by muse, mutect2, varscan2
- TIPRL | c.*2A>G | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- ZPLD1 | c.-163G>A | 5'UTR (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
